Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J2, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J2-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Date of Birth:

Sex: Female

IED-03
Carcinoma, adrenal cortical
Site (L) Adrenal Gland Cortex
8/3/13
674.0
JW 5/1/13

Macroscopy

Two vessels containing a material immersed in formaldehyde solution, described as following: 1. product of en-bloc resection of the left kidney, spleen and left adrenal mass. The mass is totally involved by a fibrous capsule (measuring from 0.1 to 0.7 cm), weights 810 g and measures 18 x 14 x 7 cm. The internal surface is yellow, with areas of fibrosis and necrosis in aproximatelu 25% of the mass. Two cystic areas of 3.0 cm each. The left kidney is macroscopically normal, measures 12 x 5 x 4 cm and weights 150 g. The spleen is macroscopically normal, measures 7 x 4 x 2.5 cm and weights 120 g. 2. "Lymph node" resection. Gray nodular structure that macroscopically resembles an accessory spleen.

Conclusion:

5/30/13
per TSS, tumor actually on (L) side.

Product of right adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 18 cm.
- Weight – 810 g
- Nuclear grade (Fuhrman) –
- Diffuse architectural pattern –
- Clear cells in < 25% of the neoplasm –
- Areas on necrosis – present
- Mitotic count –
- Atypical mitosis –
- Capsular invasion – present

[page 2 of 2]
- ☒ Venous invasion – present
- Sinusoidal invasion –
- ☒ WEISS SCORE = 8
- Presence of extra capsular extension

Immunohistochemical markers:

- Melan A – focally positive
- Inhibin – focally positive
- 35BH11 – focally positive
- AE1 / AE3 – focally positive
- CD10 – focally positive
- S-100 protein – positive
- Vimentin – positive
- Chromogranin – negative
- Synaptophysin - negative

Pathologists:

Criteria	W 1/24/13	Yes	No
IHP/SA Discrepancy			

Source: NCI Genomic Data Commons file 5fda9646-6f20-49cc-828d-fc2175957464 (TCGA-OR-A5J2.345C34EE-F031-41A4-B955-BA054F2A3CE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).